Surgical pathology report (de-identified scan), TCGA case TCGA-49-6745, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-6745-01A (Primary Tumor).

[page 1 of 2]
SURG PATH REPORT

COLLECTION DATE/TIME:

1st Specimen collected

Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1. LYMPH NODE, L11 (EXCISION): METASTATIC CARCINOMA INVOLVING ONE
(1) FRAGMENTED LYMPH NODE.

2. LUNG, LEFT UPPER LOBE (LOBECTOMY):

SPECIMEN TYPE:

Lobectomy

TUMOR SITE:

Left upper lobe

HISTOLOGIC TYPE:

Adenocarcinoma with focal papillary component.

TUMOR SIZE:

4.0 cm

HISTOLOGIC GRADE:

G3: Poorly differentiated

LYMPH NODES (INCLUDES ALL PARTS):

Metastatic carcinoma in 6 of 11 lymph nodes

EXTENT OF INVASION (7th Edition, AJCC): PRIMARY TUMOR:

pT2a: Tumor more than 3 cm but 5 cm or less

REGIONAL LYMPH NODES:

pN2: Metastasis in ipsilateral subcarinal lymph nodes

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from nearest

margin: 4.0 mm (parenchymal)

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

Absent

LYMPHATIC (SMALL VESSEL) INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Emphysematous changes

3. LYMPH NODES, STATION 5 (EXCISION): TWO (2) LYMPH NODES, NEGATIVE
FOR TUMOR.

4. LYMPH NODES, STATION 7 (EXCISION): METASTATIC CARCINOMA
INVOLVING ONE (1) OF TWO (2) LYMPH NODES.

NOTE: The tumor has a focal solid component, raising the
differential diagnosis of squamous cell carcinoma.

Immunohistochemically the tumor cells are strongly positive for
Napsin-A, TTF-1, focally weakly positive for p63, and negative for CK
5/6, supporting the diagnosis of adenocarcinoma. Histochemical stain
for mucin (mucicarmine) is negative. Visceral pleura uninvolved on
VVG special stain (performed on three separate blocks). This case
was shown at the

ADDENDUM ----- Pathologist:

MOLECULAR ANALYSIS FOR EGFR AND KRAS MUTATIONS WILL BE PERFORMED AND

[page 2 of 2]
ADDENDUM ----- Pathologist: [REDACTED]

KRAS MUTATIONAL ANALYSIS

BLOCK TESTED: 2D

RESULT: NEGATIVE

NOTE: The assay did not detect a mutation in either codon 12 or 13 of the KRAS gene. A copy of the complete report is available in EPR (Lab: [REDACTED]) and is also on file in the [REDACTED]. EGFR mutational analysis is pending and will be reported as an addendum.

ADDENDUM ----- Pathologist: [REDACTED]

EGFR MUTATIONAL ANALYSIS

BLOCK TESTED: 2D

RESULT: NEGATIVE

NOTE: No mutations were identified. This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain. A copy of the complete report is available in [REDACTED] and is also on file in the [REDACTED].

***** End of Diagnosis *****

Clinical History:

QUESTION LUNG CANCER

See [REDACTED] Clinical Document dated [REDACTED] for official report.

Source: NCI Genomic Data Commons file 669342e4-118a-4e9b-832d-f96c544b56ea (TCGA-49-6745.E291AD97-8658-435D-AE71-F0EB80BBB816.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).